CCDI case PBCANC — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/830e44e6-c136-4128-8a62-af5c3d28c02d

Demographics
Sex at birth: male; Race: black or african american; Vital status: Alive.

Diagnoses (1)
1. Neoplasm, uncertain whether benign or malignant: ICD-O-3 morphology code: 8000/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.3 years (3,388 days).

Biospecimens (3 samples)
- Sample 0DN1B0: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DN1BO: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DN1CY: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
